Somatic mutation profile of tumor specimen TCGA-CV-A6JN-01A (aliquot TCGA-CV-A6JN-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G1; Age at diagnosis: 53.8 years (19,635 days).
Specimen TCGA-CV-A6JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37c260a6-17fc-429a-8bdc-11f7f8f46568.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JN-10A (Blood Derived Normal), aliquot TCGA-CV-A6JN-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f9a2c8-cbf8-48c7-ba22-86ccedaba9fc

The open-access MAF lists 84 somatic variants for this specimen: 66 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 59, Silent 18, Nonsense Mutation 5, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL441992.2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs778926559, COSV56916365; called by muse, mutect2, varscan2
- AMD1 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100924469; called by muse, mutect2, varscan2
- ARID2 | c.3952C>T p.Q1318* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57600698; called by muse, mutect2, varscan2
- BRICD5 | c.592G>T p.G198C (on ENST00000562360; = p.G198W on NM_182563.3) | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100063320; called by muse, mutect2, varscan2
- C12orf40 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as COSV100209825; called by muse, mutect2, varscan2
- CFAP92 | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99414664; called by muse, mutect2, varscan2
- CHD4 | c.5204A>G p.Y1735C (on ENST00000357008 / NM_001363606.2; = p.Y1746C on NM_001273.5) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100537607; called by muse, mutect2, varscan2
- CPZ | c.824G>A p.R275H (on ENST00000360986 / NM_001014447.3; = p.R264H on NM_003652.3) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749063388, COSV59921949; called by muse, mutect2, varscan2
- CRHR1 | c.344A>C p.H115P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99523438; called by mutect2, varscan2
- DCAF10 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.265); catalogued as rs371428227; called by muse, mutect2, varscan2
- DMBX1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780357986, COSV63601858; called by muse, mutect2, varscan2
- EIF2AK3 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.772); catalogued as COSV100303593; called by muse, mutect2, varscan2
- EIF4G1 | c.964G>A p.E322K (on ENST00000346169 / NM_198241.3; = p.E126K on NM_004953.5) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.935); catalogued as rs1409430751, COSV59990698; called by muse, mutect2, varscan2
- EPAS1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747275399, COSV99763044, COSV99763401; called by muse, mutect2, varscan2
- FBXO21 | c.1811A>G p.Y604C (on ENST00000330622 / NM_033624.3; = p.Y597C on NM_015002.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57972319; called by muse, mutect2, varscan2
- GCNT3 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV101251773; called by muse, mutect2, varscan2
- GGT1 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV99958719; called by muse, mutect2, varscan2
- GOSR2 | c.228G>C p.R76S (on ENST00000393456 / NM_001321134.1; = p.R94S on NM_004287.5) | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99846017; called by muse, mutect2, varscan2
- H1-10 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100412922; called by muse, mutect2
- HELQ | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99787532; called by muse, mutect2
- HLA-E | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64927732; called by muse, mutect2, varscan2
- IL21R | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767388017, COSV61969748; called by muse, mutect2, varscan2
- KCNS3 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs556337820, COSV100411104; called by muse, mutect2, varscan2
- KDM5A | c.2940A>T p.E980D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV101238694; called by muse, mutect2, varscan2
- LTBP1 | c.4238C>T p.S1413L (on ENST00000404816 / NM_206943.4; = p.S1087L on NM_000627.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV99698027; called by muse, mutect2
- MB21D2 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101165065; called by muse, mutect2, varscan2
- MTMR8 | c.1412G>T p.R471M | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100878386; called by muse, mutect2, varscan2
- MYCBP2 | c.662T>C p.I221T (on ENST00000357337; = p.I259T on NM_015057.5) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100629690; called by muse, mutect2, varscan2
- MYLK | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs770980369, COSV100658752; called by muse, mutect2, varscan2
- MYO1E | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.05); catalogued as rs1037256063, COSV99894995; called by muse, mutect2, varscan2
- MYORG | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.279); catalogued as rs764275725, COSV99898453; called by muse, mutect2, varscan2
- NCCRP1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as rs760512302, COSV59212159; called by muse, mutect2, varscan2
- NOSIP | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs1303135812, COSV100182177; called by muse, mutect2, varscan2
- OR4P4 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV100111657; called by muse, mutect2, varscan2
- PDS5A | c.2045C>A p.S682Y | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as COSV100337254; called by muse, mutect2, varscan2
- PKD2L2 | c.1736T>A p.M579K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99221187; called by muse, mutect2, varscan2
- PPFIA2 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100332478; called by muse, mutect2, varscan2
- PPP1R9A | c.2876A>G p.E959G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99195003; called by muse, mutect2, varscan2
- QARS1 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100069846; called by muse, mutect2, varscan2
- RAP1GAP | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs1253951389, COSV51572431; called by muse, mutect2, varscan2
- RHBDD2 | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV99138223; called by muse, mutect2, varscan2
- RHCE | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV53799606; called by muse, mutect2, varscan2
- RINT1 | c.1581G>C p.E527D | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as COSV99994305; called by muse, mutect2, varscan2
- RMDN2 | c.941A>G p.Y314C (on ENST00000354545 / NM_001322212.2; = p.Y492C on NM_144713.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99307476; called by muse, mutect2, varscan2
- SACS | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101207275; called by muse, mutect2, varscan2
- SERPINA10 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV100003715; called by muse, mutect2
- SHROOM3 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV56024058; called by muse, mutect2
- SIN3A | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100845090; called by muse, mutect2
- SLC25A3 | c.1048A>T p.M350L (on ENST00000228318 / NM_005888.3; = p.M349L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV99499067; called by muse, mutect2, varscan2
- SLC52A1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV54693878; called by muse, mutect2, varscan2
- TAPBP | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV101444927; called by muse, mutect2, varscan2
- TBC1D8B | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99344111; called by muse, mutect2, varscan2
- TENT4B | c.1553A>G p.Y518C (on ENST00000561678 / NM_001365323.2; = p.Y503C on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665818; called by muse, mutect2, varscan2
- TEX44 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs140125501, COSV100009650; called by muse, mutect2, varscan2
- THSD7A | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101448597; called by muse, mutect2, varscan2
- TLN1 | c.5879A>T p.K1960M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100147519; called by muse, mutect2, varscan2
- TOP3A | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV100328987; called by muse, mutect2, varscan2
- TRIM3 | c.788C>A p.S263* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100624304; called by muse, mutect2, varscan2
- TRPC4 | c.2847T>A p.H949Q (on ENST00000379705 / NM_016179.4; = p.H954Q on NM_003306.3) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.019); catalogued as COSV100156348; called by muse, mutect2, varscan2
- VPS13A | c.1646C>A p.S549* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100652430, COSV62424405; called by muse, mutect2, varscan2
- ZBTB20 | c.1459C>G p.L487V (on ENST00000474710 / NM_001164342.2; = p.L414V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100613258, COSV61872649; called by muse, mutect2, varscan2
- ZGRF1 | c.2900A>G p.D967G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1218150710, COSV100005422; called by muse, mutect2, varscan2
- ZKSCAN5 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV100460076; called by muse, mutect2, varscan2
- ZNF277 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100702361; called by muse, mutect2, varscan2
- MLC1 | c.682_686del p.L228Sfs*62 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- TP53 | c.408_411del p.L137Pfs*32 | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.3123C>T p.A1041= (on ENST00000368013 / NM_001025598.2; = p.A830= on NM_181720.3) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100920180; called by muse, mutect2, varscan2
- BCR | c.1452C>T p.S484= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100006260; called by muse, mutect2, varscan2
- CARD10 | c.1992C>T p.A664= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs749725348, COSV52659269, COSV99324780; called by muse, mutect2, varscan2
- CYFIP1 | c.3321C>G p.P1107= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100487995; called by muse, mutect2, varscan2
- DHX16 | c.2961C>T p.H987= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs572330004, COSV99527822; called by muse, mutect2, varscan2
- DSG1 | c.975A>G p.R325= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99935755; called by muse, mutect2, varscan2
- FANCM | c.2058A>G p.K686= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99950789; called by muse, mutect2
- GPR45 | c.618G>A p.A206= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs376637446, COSV99306850; called by muse, mutect2, varscan2
- ITGA10 | c.1383C>T p.I461= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs782549509, COSV100994801; called by muse, mutect2, varscan2
- KIAA0408 | c.1605T>C p.N535= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100846848; called by muse, mutect2, varscan2
- MAB21L4 | c.375C>T p.T125= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs773072905, COSV100278454; called by muse, mutect2
- NBEAL1 | c.4299A>G p.Q1433= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs898297652, COSV101495632; called by muse, mutect2, varscan2
- PRDM12 | c.75C>T p.A25= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs761704631, COSV99446148; called by muse, mutect2, varscan2
- RANBP17 | c.3252C>T p.L1084= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs771836030, COSV101206019; called by muse, mutect2, varscan2
- RNF123 | c.591C>T p.I197= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs774631951, COSV59684729; called by muse, mutect2, varscan2
- SLCO3A1 | c.969G>T p.L323= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100575143; called by muse, mutect2, varscan2
- ZDHHC14 | c.1272G>A p.A424= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs376404349; called by muse, mutect2, varscan2
- ZNF816 | c.408T>A p.T136= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV99554516; called by muse, mutect2, varscan2
